Gene-level copy-number profile of tumor specimen TCGA-60-2704-01A from TCGA case TCGA-60-2704, project TCGA-LUSC (Lung Squamous Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IIB; Age at diagnosis: 73.7 years (26,927 days).
Specimen TCGA-60-2704-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-LUSC.37ad5697-eb48-40f1-b7ee-979a14665550.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-60-2704-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c87b2be8-95d1-4fbf-a4bb-c2d1348bac40

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 82; copy number 1: 1,401; copy number 2: 33,489; copy number 3: 18,926; copy number 4: 3,867; copy number 5: 784; copy number 6: 111; copy number 7: 426; copy number 8: 206; copy number 9: 348; copy number 11: 27; copy number 12: 65; copy number 14: 24; copy number 19: 22; copy number 22: 37.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-60-2704-01A-11D-2041-01): tumor purity 0.21, ploidy 2.97, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 82 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:19,507,452–23,682,662, 82 genes (within-gene range 0–4) (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 2,016 genes in 17 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:141,660,536–198,222,513, 986 genes, copy number 5–9 (broad region; genes not listed).
- chr4:176,844,493–178,116,861, 14 genes, copy number 7: AC097518.2, AC092673.1, LINC02509, RN7SKP136, AC097518.1, NEIL3, AC027627.1, AGA, AC078881.1, RNA5SP172, AC103879.1, LINC01098, LINC01099, RNU1-45P.
- chr8:41,298,163–42,555,195, 37 genes, copy number 6–19: RNU6-895P, SNORD65B, AC016868.1, GOLGA7, AC009630.1, KRT18P37, GINS4, AC009630.2, AC009630.4, GPAT4, AC009630.3, NKX6-3, ANK1, MIR486-1, MIR486-2, AC113133.1, Y_RNA, AC027702.1, RN7SL149P, KAT6A, AC090571.1, AC103724.1, AC103724.2, AC103724.4, AC103724.3, AP3M2, PLAT, AC083973.1, IKBKB, POLB, RPL5P23, DKK4, VDAC3, SLC20A2, AC093367.1, AC090739.1, SMIM19.
- chr9:23,690,104–25,938,434, 14 genes, copy number 5 (within-gene range 0–5): ELAVL2, AL161628.1, AL365204.1, AL365204.2, AL365204.3, AL513317.1, IZUMO3, AL353811.1, RMRPP5, RN7SKP120, AL353730.1, TUSC1, LINC01241, FAM71BP1.
- chr9:68,705,240–69,009,176, 1 gene, copy number 6 (within-gene range 4–6): PIP5K1B.
- chr9:68,935,873–74,693,177, 66 genes, copy number 6–8 (within-gene range 3–8) (broad region; genes not listed).
- chr12:18,242,961–22,008,880, 55 genes, copy number 7–12 (within-gene range 3–12): PIK3C2G, NDFIP1P1, AC092851.1, ZKSCAN7P1, PLCZ1, PSMC1P9, AC087242.1, CAPZA3, RPL7P6, MEF2BNBP1, PLEKHA5, AC092828.1, RN7SL459P, RN7SL67P, AEBP2, PDCD5P1, AC091805.2, RNU6-254P, EEF1A1P4, AC091805.1, AC137561.1, RNU1-146P, AC024901.1, TCP1P3, LINC02398, AC126468.1, LINC02468, AC129102.1, PDE3A, UBE2L2, AC112777.1, SLCO1C1, SLCO1B3, SLCO1B3-SLCO1B7, AC011604.1, SLCO1B7, AC022335.1, SLCO1B1, SLCO1A2, IAPP, PYROXD1, ELOCP31, RECQL, GOLT1B, SPX, GYS2, AC010197.2, LDHB, AC010197.1, AC010185.1, KCNJ8, ABCC9, AC008250.1, AC008250.2, AC092862.1.
- chr12:29,142,969–34,249,958, 118 genes, copy number 6–14 (broad region; genes not listed).
- chr12:69,212,108–69,959,097, 22 genes, copy number 5: AC127894.1, CPSF6, MIR1279, C1GALT1P1, AC020656.2, LYZ, AC020656.1, YEATS4, RN7SL804P, RPS26P45, LINC02373, FRS2, MIR3913-1, MIR3913-2, CCT2, LRRC10, BEST3, AC025263.3, AC025263.1, RAB3IP, AC025263.2, MYRFL.
- chr12:69,946,543–69,947,081, 1 gene, copy number 5: AC078922.1.
- chr13:107,163,510–107,867,496, 1 gene, copy number 6 (within-gene range 3–6): FAM155A.
- chr13:107,465,984–114,337,626, 133 genes, copy number 6–22 (broad region; genes not listed).
- chr19:55,785,397–58,605,223, 190 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr20:5,482,736–24,446,314, 317 genes, copy number 5 (within-gene range 4–5) (broad region; genes not listed).
- chr20:24,491,472–24,502,345, 1 gene, copy number 5: AL157413.1.
- chr20:37,178,410–38,962,111, 58 genes, copy number 12: RPN2, GHRH, MANBAL, AL034422.1, SRC, RPL7AP14, BLCAP, NNAT, AL109614.1, PPIAP3, LINC01746, GLRXP1, LINC00489, AL162293.1, CTNNBL1, VSTM2L, RN7SKP185, TTI1, RPRD1B, RN7SL237P, AL031651.1, TGM2, KIAA1755, AL031651.2, AL359555.3, AL359555.4, AL359555.2, AL359555.1, BPI, LBP, AL391095.2, AL391095.1, AL391095.3, SNHG17, SNORA71, SNORA71B, SNORA71A, SNORA71C, SNORA71D, SNORA71, SNHG11, SNORA71E, SNORA60, RALGAPB, MIR548O2, RPS3P2, ADIG, ARHGAP40, AL035419.1, Metazoa_SRP, SLC32A1, ACTR5, RN7SKP173, PPP1R16B, RN7SL116P, FAM83D, AL023803.2, AL023803.1.
- chr20:38,962,472–38,978,422, 2 genes, copy number 12: AL023803.3, NPM1P19.

Autosomal genes at a single copy (total copy number 1): 607. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
